Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5453, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5453-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/Adden
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

TCGA-CZ-5453

***** Addended Report *****

PATHOLOGIC DIAGNOSIS:

LEFT KIDNEY AND ADRENAL GLAND, NEPHRECTOMY:

RENAL CELL CARCINOMA (7.2 cm), clear cell type, Fuhrman nuclear grade II of IV.

Tumor does not invade the renal capsule.

No vascular invasion identified.

Ureteric, vascular, and soft tissue margins are negative for tumor.

Benign renal cyst (2.5 cm).

Adrenal gland with no significant pathologic change.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

AJCC Classification (6th Edition): T2 NX MX.

CLINICAL DATA:

History: None given.

Operation: Attempted laparoscopic nephrectomy.

Clinical Diagnosis: Renal cancer.

TISSUE SUBMITTED:

A/1) L kidney and adrenal gland -- Tissue Bank.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patients name, unit number, and "#1 - L kidney", and consists of a 947.5 gram left radical nephrectomy specimen, including kidney (20.5 x 14.5 x 7.2 cm) and left adrenal gland (6 x 1.8 x 0.4 cm), with surrounding perirenal fat, measuring in thickness from 2-3 cm. Extending from the renal pelvis is a ureter (9 cm in length x 0.3 cm in diameter), renal vein (2.2 cm in length x 1.0 cm in diameter), renal artery #1 (2.1 cm in length x 0.5 cm in diameter) and renal artery #2 (2.5 cm in length x 0.3 cm in diameter). In the lower pole there is a tan/red to tan/yellow multilobulated mass (7.2 x 6.5 x 5.5 cm). The tumor abuts the kidney capsule, 0.1 cm to ink, 9.0 cm to the ureter, 3.4 cm to artery #1, 4.8 cm to artery #2, and 2.2 cm to the vein margin. The tumor is located 0.6 cm from the closest vein without invasion. The tumor abuts Gerota's fascia. There is also a large cystic cavity (1.2 x 3.0 x 2.5 cm) in the upper pole. The adipose tissue is thinly sectioned and no lymph nodes are found. Representative sections of the tumor are submitted for electron microscopy, cytogenetics, quick fix and Tumor Bank. Representative sections of the normal kidney are submitted for electron microscopy, immunofluorescence and Tumor Bank.

Micro A1: tumor in capsule and perirenal fat, 2 frags, [REDACTED]

Micro A2: tumor and adjacent normal kidney, 1 frag, [REDACTED]

Micro A3: tumor and renal vein, 1 frag, [REDACTED]

Micro A4: renal vein, artery #1 and artery #2 in ureter margins, 4 frags, [REDACTED]

Micro A5: T1 quick fix, 1 frag, [REDACTED]

Micro A6: T2 quick fix, 1 frag, [REDACTED]

Micro A7: tumor to Gerota's fascia (inked yellow), 1 frag, [REDACTED]

Micro A8: adrenal gland, 2 frags, [REDACTED]

Micro A9: normal kidney, 1 frag, [REDACTED]

Micro A10: renal cyst, 1 frag, [REDACTED]

[page 2 of 2]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist: [REDACTED]

Report Status: Final

TCGA-CZ-5453

KARYOTYPE:

T1:40-44,XY,der(2)t(2;3)(q376;q173),-3,-8,add(14)(q32)[cp5]/85-88,idem x2[cp7]

METAPHASES COUNTED: 12 ANALYZED: 5 SCORED: 7 BANDING: GTG

INTERPRETATION:

Each of 12 metaphases contained clonal aberrations that included deletion of the chromosome 3 short arm (3p). This is a typical cytogenetic aberration in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC

Source: NCI Genomic Data Commons file 7f9841c8-1417-4479-b0ba-933c14bde924 (TCGA-CZ-5453.99715118-DC84-4FD0-868D-06D2399D5528.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).